Somatic mutation profile of tumor specimen TCGA-RC-A7SH-01A (aliquot TCGA-RC-A7SH-01A-11D-A382-10) from TCGA case TCGA-RC-A7SH, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, clear cell type; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 42.6 years (15,560 days).
Specimen TCGA-RC-A7SH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c44121e3-b22f-4e3d-b5d6-7964cc38995f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-RC-A7SH-10A (Blood Derived Normal), aliquot TCGA-RC-A7SH-10A-01D-A385-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/269b765f-c17a-4223-b957-3ff445051629

The open-access MAF lists 74 somatic variants for this specimen: 55 protein-altering or splice-affecting, 17 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, Silent 17, Nonsense Mutation 5, Frame Shift Del 2, Translation Start Site 1, In Frame Del 1, 3'Flank 1, 5'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.589G>T p.V197L | Missense Mutation (SNP) | VAF 66/85 reads (78%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.664); catalogued as rs786204041, CM070297, COSV52711079, COSV52927251, COSV53163944; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- A2M | c.1891C>A p.P631T | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT tolerated (0.31); PolyPhen benign (0.104); catalogued as COSV100588502; called by muse, mutect2, varscan2
- APAF1 | c.1859A>G p.H620R (on ENST00000551964 / NM_181861.2; = p.H609R on NM_001160.3) | Missense Mutation (SNP) | VAF 55/115 reads (48%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.903); catalogued as rs1176032182, COSV100452331; called by muse, mutect2, varscan2
- ARID2 | c.2716G>C p.V906L | Missense Mutation (SNP) | VAF 13/175 reads (7%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0); catalogued as COSV100535550; called by muse, mutect2
- ATP6V1D | c.736T>C p.F246L | Missense Mutation (SNP) | VAF 41/50 reads (82%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV99370757; called by muse, mutect2, varscan2
- C8orf76 | c.1043T>C p.V348A | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99414874; called by muse, mutect2, varscan2
- CBY2 | c.1022A>G p.E341G | Missense Mutation (SNP) | VAF 25/33 reads (76%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.997); catalogued as COSV100137479; called by muse, mutect2, varscan2
- CCDC141 | c.2095A>T p.K699* | Nonsense Mutation (SNP) | VAF 34/70 reads (49%) | catalogued as COSV99836283; called by muse, mutect2, varscan2
- CDH9 | c.1957C>T p.R653W | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50320975, COSV99142080; called by muse, mutect2, varscan2
- CHKB | c.408C>G p.Y136* | Nonsense Mutation (SNP) | VAF 101/219 reads (46%) | catalogued as COSV100376517; called by muse, mutect2, varscan2
- COL22A1 | c.338G>A p.G113D | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs375895986, COSV100279115; called by muse, mutect2, varscan2
- CWC22 | c.2161G>C p.G721R | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0); catalogued as COSV99844031; called by muse, mutect2, varscan2
- EFCAB14 | c.1105A>G p.K369E | Missense Mutation (SNP) | VAF 34/46 reads (74%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV100905554; called by muse, mutect2, varscan2
- ELOVL4 | c.572T>A p.I191N | Missense Mutation (SNP) | VAF 43/125 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100876184; called by muse, mutect2, varscan2
- ERCC4 | c.2455A>G p.S819G | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100318706; called by muse, mutect2
- FAM20A | c.826del p.R276Dfs*10 | Frame Shift Del (DEL) | VAF 25/72 reads (35%) | catalogued as CM120326; called by mutect2, pindel, varscan2
- FIGN | c.2152C>A p.P718T | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.066); catalogued as COSV100291688; called by muse, mutect2, varscan2
- FRMD7 | c.1871C>A p.T624K | Missense Mutation (SNP) | VAF 88/98 reads (90%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs751858239, COSV100048732, COSV53746893; called by muse, varscan2
- GBA3 | c.1381C>T p.R461* | Nonsense Mutation (SNP) | VAF 45/119 reads (38%) | catalogued as rs538670192, COSV101545479, COSV101545563; called by muse, mutect2, varscan2
- GORASP2 | c.125C>T p.S42F | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99304469; called by muse, mutect2, varscan2
- HDGFL1 | c.220G>A p.G74S | Missense Mutation (SNP) | VAF 49/103 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV100014509; called by muse, mutect2, varscan2
- HSPA13 | c.449G>C p.R150P | Missense Mutation (SNP) | VAF 47/140 reads (34%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.863); catalogued as COSV99579923; called by muse, mutect2, varscan2
- HTR1F | c.740T>A p.L247Q | Missense Mutation (SNP) | VAF 45/51 reads (88%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as COSV100137981; called by muse, mutect2, varscan2
- ITIH6 | c.1828A>G p.M610V | Missense Mutation (SNP) | VAF 90/102 reads (88%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99512937; called by muse, mutect2, varscan2
- KCNH8 | c.2443G>A p.D815N | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs373726349; called by muse, mutect2, varscan2
- KLHL9 | c.1498G>T p.G500C | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100757010; called by muse, mutect2, varscan2
- LIPN | c.37T>C p.C13R | Missense Mutation (SNP) | VAF 41/115 reads (36%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs374782630; called by muse, mutect2, varscan2
- LNPEP | c.801A>G p.I267M | Missense Mutation (SNP) | VAF 75/138 reads (54%) | SIFT deleterious (0.04); PolyPhen benign (0.043); catalogued as COSV99183484; called by muse, mutect2, varscan2
- LURAP1L | c.322A>G p.R108G | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100070595; called by muse, mutect2, varscan2
- MAGEB18 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 45/49 reads (92%) | SIFT tolerated (0.08); PolyPhen benign (0.036); catalogued as COSV100305319; called by muse, mutect2, varscan2
- MAP7D2 | c.1511T>C p.I504T | Missense Mutation (SNP) | VAF 71/84 reads (85%) | SIFT deleterious (0); PolyPhen possibly damaging (0.5); catalogued as COSV101107199, COSV65527810; called by muse, mutect2, varscan2
- MMP16 | c.911C>T p.P304L | Missense Mutation (SNP) | VAF 74/227 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as rs772275333, COSV54173568, COSV54192724; called by muse, mutect2, varscan2
- NCEH1 | c.1256G>A p.G419E (on ENST00000538775; = p.G379E on NM_020792.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/155 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1396124353, COSV99859876; called by muse, mutect2, varscan2
- NCOA1 | c.2302C>G p.L768V | Missense Mutation (SNP) | VAF 109/285 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.967); catalogued as COSV99945370; called by muse, mutect2, varscan2
- ODF4 | c.358G>T p.V120F | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as COSV100071818; called by muse, mutect2
- OPA1 | c.2572G>T p.E858* (on ENST00000361510 / NM_130837.3; = p.E803* on NM_015560.3) | Nonsense Mutation (SNP) | VAF 117/274 reads (43%) | catalogued as COSV100655184; called by muse, mutect2, varscan2
- OPA1 | c.2573A>T p.E858V (on ENST00000361510 / NM_130837.3; = p.E803V on NM_015560.3) | Missense Mutation (SNP) | VAF 120/276 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV100655186; called by muse, mutect2, varscan2
- PACRGL | c.41A>T p.N14I | Missense Mutation (SNP) | VAF 217/627 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.117); catalogued as COSV99763926; called by muse, mutect2, varscan2
- PPP1R3A | c.1670C>T p.A557V | Missense Mutation (SNP) | VAF 63/123 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.03); catalogued as rs536084008, COSV99492149; called by muse, mutect2, varscan2
- R3HCC1L | c.2036A>G p.D679G (on ENST00000612478 / NM_001256619.2; = p.D665G on NM_014472.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 67/109 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100107130; called by muse, mutect2, varscan2
- RARS1 | c.1364G>A p.R455H | Missense Mutation (SNP) | VAF 19/286 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs199894860, COSV51565191; called by muse, mutect2
- RASA1 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 52/116 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.267); catalogued as COSV99169642; called by muse, mutect2, varscan2
- SLITRK2 | c.751G>A p.G251R | Missense Mutation (SNP) | VAF 71/76 reads (93%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV59425040; called by muse, mutect2, varscan2
- SPECC1 | c.260A>G p.E87G | Missense Mutation (SNP) | VAF 74/166 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs757526242, COSV99821375; called by muse, mutect2, varscan2
- SPTA1 | c.5062A>C p.K1688Q | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as COSV100934464; called by muse, varscan2
- TCF25 | c.1333C>T p.Q445* | Nonsense Mutation (SNP) | VAF 33/40 reads (83%) | catalogued as COSV99642439; called by muse, mutect2, varscan2
- TM7SF3 | c.1027A>G p.K343E | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.72); PolyPhen benign (0.096); catalogued as COSV100544670; called by muse, mutect2, varscan2
- TM9SF2 | c.254A>T p.Q85L | Missense Mutation (SNP) | VAF 49/74 reads (66%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as COSV100899668; called by muse, mutect2, varscan2
- TMEM161A | c.1343G>A p.R448H | Missense Mutation (SNP) | VAF 97/257 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99365386; called by muse, mutect2, varscan2
- TUBA3D | c.889G>A p.E297K | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.85); catalogued as COSV100342373; called by muse, mutect2, varscan2
- UBE4B | c.2731A>G p.I911V (on ENST00000343090 / NM_001105562.3; = p.I782V on NM_006048.5) | Missense Mutation (SNP) | VAF 78/90 reads (87%) | SIFT tolerated (0.11); PolyPhen benign (0.014); catalogued as COSV99475871; called by muse, mutect2, varscan2
- ADGRL1 | c.1217C>T p.A406V (on ENST00000340736 / NM_001008701.3; = p.A401V on NM_014921.5) | Missense Mutation (SNP) | VAF 3/51 reads (6%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2
- BRCC3 | c.541dup p.S181Kfs*21 | Frame Shift Ins (INS) | VAF 292/330 reads (88%) | called by mutect2, varscan2
- MARCKSL1 | c.309_322del p.F105Efs*6 | Frame Shift Del (DEL) | VAF 9/13 reads (69%) | called by mutect2, varscan2
- SLC25A47 | c.877_879del p.F293del | In Frame Del (DEL) | VAF 22/32 reads (69%) | called by mutect2, pindel, varscan2
- AR | c.2166C>A p.A722= | Silent (SNP) | VAF 22/175 reads (13%) | catalogued as CD025334, COSV101017582; called by muse, mutect2, varscan2
- BHLHE41 | c.1443T>A p.A481= | Silent (SNP) | VAF 52/125 reads (42%) | catalogued as COSV99658222; called by muse, mutect2, varscan2
- BICC1 | c.2655G>C p.L885= | Silent (SNP) | VAF 8/146 reads (5%) | catalogued as COSV99570288; called by muse, mutect2
- CACNA1E | c.5730G>A p.E1910= | Silent (SNP) | VAF 95/338 reads (28%) | catalogued as rs1360170031, COSV100701401, COSV62406610; called by muse, mutect2, varscan2
- CALHM5 | c.909G>T p.V303= | Silent (SNP) | VAF 8/57 reads (14%) | catalogued as COSV100635527, COSV62067970; called by muse, mutect2, varscan2
- CIART | c.231A>G p.P77= | Silent (SNP) | VAF 138/292 reads (47%) | catalogued as COSV99290146; called by muse, mutect2, varscan2
- ELOVL4 | c.573C>A p.I191= | Silent (SNP) | VAF 45/126 reads (36%) | catalogued as COSV100876182, COSV63953489; called by muse, mutect2, varscan2
- GABRA6 | c.405C>T p.L135= | Silent (SNP) | VAF 24/115 reads (21%) | catalogued as COSV99194119; called by muse, mutect2, varscan2
- HOXA7 | c.45G>T p.T15= | Silent (SNP) | VAF 82/200 reads (41%) | catalogued as COSV99636271; called by muse, mutect2, varscan2
- HOXC4 | c.381C>T p.S127= | Silent (SNP) | VAF 77/92 reads (84%) | catalogued as COSV100323962; called by muse, mutect2, varscan2
- INPP5F | c.3354T>C p.L1118= | Silent (SNP) | VAF 62/126 reads (49%) | catalogued as COSV100740011; called by muse, mutect2, varscan2
- MAGEB16 | c.111C>T p.T37= | Silent (SNP) | VAF 17/77 reads (22%) | catalogued as COSV101303284; called by muse, mutect2, varscan2
- PRRC2B | c.1362G>A p.P454= | Silent (SNP) | VAF 13/72 reads (18%) | catalogued as rs565217318, COSV100621538, COSV61944517; called by muse, mutect2, varscan2
- SLC4A2 | c.1467A>T p.P489= | Silent (SNP) | VAF 51/87 reads (59%) | catalogued as COSV100054931; called by muse, mutect2, varscan2
- SLC9B2 | c.228G>A p.L76= | Silent (SNP) | VAF 53/64 reads (83%) | catalogued as COSV100293842; called by muse, mutect2, varscan2
- TBL1X | c.1365A>G p.K455= | Silent (SNP) | VAF 155/168 reads (92%) | catalogued as COSV99482205; called by muse, mutect2, varscan2
- ZIM2 | c.1563T>C p.T521= | Silent (SNP) | VAF 53/120 reads (44%) | catalogued as COSV99687706; called by muse, mutect2, varscan2
- FCAR | c.-2C>T | 5'UTR (SNP) | VAF 10/154 reads (6%) | catalogued as rs773500089, COSV100628994; called by muse, mutect2
- MFSD12 | chr19:3542782 T>A | 3'Flank (SNP) | VAF 16/50 reads (32%) | catalogued as COSV100281283; called by muse, mutect2, varscan2
